Somatic mutation profile of tumor specimen TCGA-20-1682-01A (aliquot TCGA-20-1682-01A-01W-0633-09) from TCGA case TCGA-20-1682, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 56.4 years (20,583 days).
Specimen TCGA-20-1682-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95ac608f-050c-44b2-a31b-a1cd55d0a965.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-20-1682-10A (Blood Derived Normal), aliquot TCGA-20-1682-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdaddfb8-5ee5-42c2-93bd-cf775f9bcfbc

The open-access MAF lists 100 somatic variants for this specimen: 79 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 17, Splice Site 4, Frame Shift Del 3, Nonsense Mutation 3, Translation Start Site 2, In Frame Del 2, 5'UTR 1, Intron 1, 5'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.1961dup p.Y655Vfs*18 | Frame Shift Ins (INS) | VAF 100/164 reads (61%) | catalogued as rs80357522; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 70/115 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACVR2A | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs760629539, COSV54019370; called by muse, mutect2, varscan2
- ADGRE2 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as rs1439992779, COSV59691401, COSV59694989; called by muse, mutect2, varscan2
- ADNP | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 214/262 reads (82%) | SIFT tolerated (0.26); PolyPhen benign (0.293); catalogued as COSV62426161; called by muse, mutect2, varscan2
- ANKRD17 | c.4498G>C p.E1500Q | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV58224209; called by muse, mutect2, varscan2
- AXDND1 | c.1026_1033del p.H343Efs*32 | Frame Shift Del (DEL) | VAF 188/407 reads (46%) | catalogued as COSV62645192; called by mutect2, pindel, varscan2
- BACE2 | c.1528T>C p.S510P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV57741426; called by muse, mutect2, varscan2
- C1orf216 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV52054274; called by muse, mutect2, varscan2
- CAMSAP1 | c.4250C>T p.S1417F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56725174; called by muse, mutect2, varscan2
- CD300LG | c.151T>C p.C51R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760783261, COSV53224834; called by muse, mutect2, varscan2
- CEP350 | c.5825G>C p.S1942T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV62606291; called by muse, mutect2, varscan2
- CHD2 | c.4269G>T p.K1423N | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); catalogued as COSV101245211; called by muse, mutect2
- CHD2 | c.4270A>G p.K1424E | Missense Mutation (SNP) | VAF 21/328 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.678); catalogued as COSV101245212; called by muse, mutect2
- CHRDL2 | c.1150G>C p.V384L (on ENST00000376332 / NM_001304415.1; = p.S402T on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV55224162; called by muse, mutect2, varscan2
- CHRDL2 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99733758; called by muse, mutect2
- CLCN1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 155/242 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV100578549, COSV58372214; called by muse, mutect2, varscan2
- COG5 | c.1242C>A p.D414E | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1396418214, COSV51757395; called by muse, mutect2, varscan2
- CPO | c.649G>C p.A217P | Missense Mutation (SNP) | VAF 175/266 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55940796; called by muse, mutect2, varscan2
- CUBN | c.10200C>G p.H3400Q | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100912070, COSV64721571; called by muse, mutect2, varscan2
- CUBN | c.1045C>A p.L349I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV64721577; called by muse, mutect2, varscan2
- DGAT2 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV99929753; called by muse, mutect2
- DNAH5 | c.1645-2A>G p.X549_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99449397; called by muse, mutect2
- ELF1 | c.1262T>A p.I421K | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV53500670; called by muse, mutect2, varscan2
- FAM135B | c.1607C>T p.T536I | Missense Mutation (SNP) | VAF 58/638 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52738299; called by muse, mutect2
- FRAS1 | c.11602C>T p.L3868F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99351514; called by muse, mutect2
- GLI1 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 120/386 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs201621277, COSV57358286, COSV57361303; called by muse, varscan2
- GPC5 | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs368333375, COSV65620610; called by muse, mutect2
- GPR32 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV54515070; called by muse, mutect2, varscan2
- GRID1 | c.1538C>A p.A513E | Missense Mutation (SNP) | VAF 68/83 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60040829; called by muse, mutect2, varscan2
- GUCY2C | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 180/317 reads (57%) | catalogued as rs760164631, COSV53789167; called by muse, mutect2, varscan2
- H2AC20 | c.266G>C p.R89P | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV58612641; called by muse, mutect2, varscan2
- HTATSF1 | c.1341C>A p.N447K | Missense Mutation (SNP) | VAF 228/576 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54479965; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs200419221, COSV56242588, COSV56281020; called by muse, mutect2, varscan2
- JRKL | c.1546A>C p.K516Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53594409; called by muse, mutect2, varscan2
- KASH5 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV71358187; called by muse, mutect2, varscan2
- KRT4 | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.578); catalogued as COSV53408718; called by muse, mutect2, varscan2
- KSR2 | c.2785G>C p.E929Q | Missense Mutation (SNP) | VAF 130/168 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100195096, COSV100196632, COSV56678072; called by muse, mutect2, varscan2
- LY96 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV53026111; called by muse, mutect2, varscan2
- MAGI3 | c.3263T>C p.I1088T | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56840268; called by muse, mutect2, varscan2
- ME3 | c.1390A>G p.I464V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as rs751563626, COSV62773907; called by muse, mutect2, varscan2
- MICU2 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV101212438, COSV101212492; called by muse, mutect2
- NEBL | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs1486952071, COSV101008928, COSV65799549; called by muse, mutect2
- NIPBL | c.3783A>C p.K1261N | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56958624; called by muse, mutect2, varscan2
- NKRF | c.1260A>T p.K420N | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV58662274; called by muse, mutect2, varscan2
- OR6C1 | c.931A>C p.S311R | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.157); catalogued as COSV101110501; called by muse, mutect2
- PC | c.2974_2976del p.K992del | In Frame Del (DEL) | VAF 8/15 reads (53%) | catalogued as rs751225998; ClinVar: uncertain significance; called by mutect2, varscan2
- PCDHGA8 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.028); catalogued as rs758463890, COSV53988513; called by muse, mutect2, varscan2
- PDILT | c.1428T>A p.Y476* | Nonsense Mutation (SNP) | VAF 190/474 reads (40%) | catalogued as COSV56703495; called by muse, mutect2, varscan2
- PEX26 | c.788G>T p.C263F | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.755); catalogued as COSV61604889; called by muse, mutect2, varscan2
- POM121L12 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV68693530; called by muse, mutect2, varscan2
- POU3F4 | c.50T>A p.L17Q | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV64540161; called by muse, mutect2, varscan2
- PPHLN1 | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1276061777, COSV56733976; called by muse, mutect2, varscan2
- RAPH1 | c.324T>G p.S108R | Missense Mutation (SNP) | VAF 143/219 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as rs371363652; called by muse, mutect2, varscan2
- RHPN2 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.058); catalogued as COSV54281941; called by muse, mutect2, varscan2
- RIMS2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 122/325 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377666095; called by muse, mutect2, varscan2
- RNPEP | c.1323T>A p.Y441* | Nonsense Mutation (SNP) | VAF 60/200 reads (30%) | catalogued as COSV55242643; called by muse, mutect2, varscan2
- SAMD9L | c.3203A>G p.E1068G | Missense Mutation (SNP) | VAF 110/577 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV59083344; called by muse, mutect2, varscan2
- SLC25A38 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.205); catalogued as COSV56194920; called by muse, mutect2
- SUZ12 | c.1742T>A p.V581E | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV59501790; called by muse, mutect2, varscan2
- SYNE1 | c.2521C>G p.L841V (on ENST00000367255 / NM_182961.4; = p.L848V on NM_033071.3) | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.114); catalogued as COSV54904049, COSV99562924; called by muse, mutect2
- SYT17 | c.1178G>C p.S393T | Missense Mutation (SNP) | VAF 129/334 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.932); catalogued as COSV62547209; called by muse, mutect2, varscan2
- TCF25 | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54530752; called by muse, mutect2
- TUBA3C | c.758C>G p.T253R | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.609); catalogued as COSV67139666; called by muse, mutect2, varscan2
- USP31 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as rs750961665, COSV54854495, COSV99565190, COSV99565377; called by muse, mutect2
- VPS4B | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.124); catalogued as rs1284114900, COSV53070125; called by muse, mutect2, varscan2
- VWF | c.7888-2A>C p.X2630_splice | Splice Site (SNP) | VAF 23/178 reads (13%) | catalogued as COSV54627407; called by muse, mutect2, varscan2
- WNT2B | c.892G>A p.D298N (on ENST00000369684 / NM_024494.3; = p.D279N on NM_004185.4) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56675747; called by muse, mutect2, varscan2
- ZDBF2 | c.4088G>T p.S1363I | Missense Mutation (SNP) | VAF 56/83 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV65628011; called by muse, mutect2, varscan2
- ZFAT | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 337/844 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs763648740, COSV64742176; called by muse, mutect2, varscan2
- ZNF564 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as rs1381944612, COSV59435803; called by muse, mutect2, varscan2
- AC005833.1 | c.1450_1462del p.D484Qfs*11 | Frame Shift Del (DEL) | VAF 44/108 reads (41%) | called by pindel, varscan2
- ARL4A | c.-14_4del | Translation Start Site (DEL) | VAF 36/112 reads (32%) | called by mutect2, pindel, varscan2
- ATP7B | c.1555_1566del p.V519_A522del | In Frame Del (DEL) | VAF 29/99 reads (29%) | called by mutect2, pindel, varscan2
- OR7E24 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLXNA3 | c.5369+4_5369+18del p.X1790_splice | Splice Site (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel
- PRAMEF19 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 160/518 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.691); called by mutect2, varscan2
- SLITRK6 | c.2286_2307del p.R764Sfs*5 | Frame Shift Del (DEL) | VAF 85/133 reads (64%) | called by pindel, varscan2*
- SMC5 | c.2151_2194del p.X717_splice | Splice Site (DEL) | VAF 34/199 reads (17%) | called by mutect2, pindel
- AC004593.2 | c.417C>T p.I139= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV56097282; called by muse, mutect2, varscan2
- DRD2 | c.21C>A p.S7= | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as COSV100669593; called by muse, mutect2
- EPB41L1 | c.1371G>A p.E457= | Silent (SNP) | VAF 50/190 reads (26%) | catalogued as rs1446724761, COSV52440954; called by muse, mutect2, varscan2
- FAT4 | c.10212C>T p.P3404= | Silent (SNP) | VAF 95/154 reads (62%) | catalogued as rs267600014, COSV58697732; called by muse, mutect2, varscan2
- FMR1NB | c.204C>A p.P68= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV65072513; called by muse, mutect2, varscan2
- IGSF1 | c.1737G>A p.L579= | Silent (SNP) | VAF 38/506 reads (8%) | catalogued as COSV100812063; called by muse, mutect2
- LLGL1 | c.1968C>T p.L656= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV57499395; called by muse, mutect2, varscan2
- NLRP10 | c.762G>A p.L254= | Silent (SNP) | VAF 70/161 reads (43%) | catalogued as COSV60781250; called by muse, mutect2, varscan2
- PLPP6 | c.774C>G p.V258= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV56306344; called by muse, mutect2, varscan2
- SH2D1A | c.246T>C p.N82= | Silent (SNP) | VAF 150/790 reads (19%) | catalogued as COSV63579472, COSV63579621; called by muse, mutect2, varscan2
- SLC2A3 | c.438G>A p.S146= | Silent (SNP) | VAF 59/189 reads (31%) | catalogued as rs747972603, COSV50005012; called by muse, mutect2, varscan2
- SLC47A1 | c.1633C>A p.R545= | Silent (SNP) | VAF 44/68 reads (65%) | catalogued as rs773686189, COSV54498951, COSV54502625; called by muse, mutect2, varscan2
- ST6GAL1 | c.39C>T p.C13= | Silent (SNP) | VAF 299/523 reads (57%) | catalogued as rs368957799; called by muse, mutect2, varscan2
- SYDE2 | c.1983T>C p.D661= | Silent (SNP) | VAF 7/121 reads (6%) | catalogued as COSV99320452; called by muse, mutect2
- TAOK3 | c.2436C>T p.Y812= | Silent (SNP) | VAF 24/205 reads (12%) | catalogued as COSV66826891; called by muse, mutect2, varscan2
- TTC33 | c.567A>G p.A189= | Silent (SNP) | VAF 89/142 reads (63%) | catalogued as COSV61802774; called by muse, mutect2, varscan2
- UGT1A8 | c.717C>T p.V239= | Silent (SNP) | VAF 27/790 reads (3%) | catalogued as rs945802131, COSV100990603; called by muse, mutect2
- ARHGAP39 | c.2522-3570A>T | Intron (SNP) | VAF 10/29 reads (34%) | catalogued as COSV52773688; called by muse, mutect2, varscan2
- EEF1A1P22 | n.143G>C | RNA (SNP) | VAF 115/163 reads (71%) | called by muse, mutect2, varscan2
- FAM71B | c.-2C>G | 5'UTR (SNP) | VAF 36/124 reads (29%) | catalogued as COSV100262077; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331447 ins C | 5'Flank (INS) | VAF 4/28 reads (14%) | catalogued as rs769456057; called by pindel, varscan2
